Somatic mutation profile of cancer-model specimen HCM-CSHL-0261-C50-85D (3D Organoid, passage 10; aliquot HCM-CSHL-0261-C50-85D-01D-A85K-36), derived from the primary tumor of HCMI case HCM-CSHL-0261-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 53.0 years (19,345 days).
Specimen HCM-CSHL-0261-C50-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d50a7b17-9e2a-4e0d-8104-718ef2eb31d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0261-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0261-C50-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2e445fa-7d23-4208-bb40-d73b98f8f9e1

The open-access MAF lists 92 somatic variants for this specimen: 69 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 21, Nonsense Mutation 3, Frame Shift Del 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 95/227 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 41/137 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD10 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV99845143; called by muse, mutect2
- ADAM21 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV50790179; called by muse, mutect2, varscan2
- ADAMTS5 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 208/403 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53178196; called by muse, mutect2, varscan2
- ATG2A | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 130/393 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs919227260; called by muse, mutect2, varscan2
- BAZ2B | c.5827G>T p.E1943* | Nonsense Mutation (SNP) | VAF 21/179 reads (12%) | catalogued as COSV58595079; called by muse, mutect2, varscan2
- CLDN10 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65299321; called by muse, mutect2, varscan2
- DDI1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770274476, COSV56381028; called by muse, mutect2, varscan2
- DDX24 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs142441892; called by muse, varscan2
- DOP1B | c.6787G>A p.D2263N | Missense Mutation (SNP) | VAF 64/503 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV67690879; called by muse, mutect2, varscan2
- DST | c.12415G>A p.E4139K (on ENST00000361203 / NM_001374722.1; = p.E1727K on NM_015548.5) | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV55017519; called by muse, mutect2, varscan2
- HMCN1 | c.10505G>A p.G3502E | Missense Mutation (SNP) | VAF 25/533 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54933471; called by muse, mutect2
- IGKV1-5 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764059454; called by muse, varscan2
- JADE3 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 116/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99510179; called by muse, mutect2, varscan2
- KIAA1671 | c.3185C>T p.S1062L | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1264243527; called by muse, mutect2, varscan2
- KRT82 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs536501280; called by muse, varscan2
- OR10J5 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 34/648 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1359654230; called by muse, mutect2
- OR52A1 | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 134/211 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as rs575135458; called by muse, mutect2, varscan2
- PCDHB15 | c.2156C>A p.A719E | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV50870072, COSV51242990; called by muse, mutect2
- PKD1 | c.4609G>A p.E1537K | Missense Mutation (SNP) | VAF 66/854 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.251); catalogued as rs781528372, CM010378, COSV51915701; called by muse, mutect2
- RAB3GAP2 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 162/336 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs777414532, COSV62784355; called by muse, mutect2, varscan2
- REM1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 173/506 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52428766; called by muse, mutect2, varscan2
- RRN3 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 27/488 reads (6%) | catalogued as COSV52213242; called by muse, mutect2
- RSPH1 | c.572T>C p.M191T | Missense Mutation (SNP) | VAF 134/300 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs914516787; called by muse, mutect2, varscan2
- SAP130 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs1339566194; called by muse, mutect2, varscan2
- SEMA5A | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 141/284 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs145947305; called by muse, mutect2, varscan2
- SH3TC1 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 212/339 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs552621094, COSV55284475; called by muse, mutect2, varscan2
- SLC35E4 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 32/555 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as rs747807094, COSV55898507; called by muse, mutect2
- TARBP1 | c.4675G>C p.E1559Q | Missense Mutation (SNP) | VAF 193/336 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50212981; called by muse, mutect2, varscan2
- TFR2 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 54/670 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as rs369355407; ClinVar: uncertain significance; called by muse, mutect2
- UNC5B | c.2341C>T p.H781Y | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1198156454; called by muse, mutect2, varscan2
- ADGB | c.4759G>A p.D1587N | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- AMER1 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 39/642 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- AP4M1 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 32/417 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ARSF | c.1616A>G p.K539R | Missense Mutation (SNP) | VAF 56/501 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASH1L | c.5324_5325del p.C1775* | Frame Shift Del (DEL) | VAF 151/376 reads (40%) | called by mutect2, pindel, varscan2
- BAIAP2L2 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 32/524 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); called by muse, mutect2
- GRIPAP1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 40/487 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- HEATR5B | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF1A | c.3632C>T p.S1211F | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KIT | c.2349del p.A784Pfs*30 | Frame Shift Del (DEL) | VAF 94/198 reads (47%) | called by mutect2, pindel, varscan2
- MAP1S | c.2726G>T p.G909V | Missense Mutation (SNP) | VAF 42/419 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NOC2L | c.389_391del p.G130del | In Frame Del (DEL) | VAF 51/259 reads (20%) | called by mutect2, pindel, varscan2
- NOTO | c.290C>G p.S97W | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- OR10AC1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 58/1109 reads (5%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2
- PCDH7 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 138/365 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, varscan2
- PDE4DIP | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2
- PILRA | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); called by muse, mutect2
- PLEKHA5 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PTK2 | c.2506G>C p.D836H | Missense Mutation (SNP) | VAF 20/417 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2
- SFMBT2 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC18A3 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 149/479 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9B1 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- SMIM19 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 105/258 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by mutect2, varscan2
- SNF8 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SPEF2 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- STRIP2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 84/556 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TBC1D4 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TCHH | c.3682G>C p.E1228Q | Missense Mutation (SNP) | VAF 46/626 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2
- TEDDM1 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 243/554 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TEX35 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 22/495 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2
- TLE6 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TRIP6 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- UNC13A | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- VPS13D | c.5447G>T p.C1816F | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- WDR74 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- WIPI1 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZGRF1 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- A2M | c.1479C>G p.L493= | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- ACTL10 | c.90G>A p.T30= | Silent (SNP) | VAF 44/508 reads (9%) | called by muse, mutect2
- ADAM15 | c.1365G>C p.L455= | Silent (SNP) | VAF 30/542 reads (6%) | called by muse, mutect2
- ASCL1 | c.372C>T p.N124= | Silent (SNP) | VAF 113/246 reads (46%) | catalogued as COSV99902170; called by muse, mutect2, varscan2
- CADPS2 | c.153C>T p.G51= | Silent (SNP) | VAF 56/1037 reads (5%) | called by muse, mutect2
- CEP192 | c.6489G>A p.L2163= | Silent (SNP) | VAF 25/217 reads (12%) | catalogued as rs772067329; called by muse, mutect2, varscan2
- CGRRF1 | c.330T>G p.A110= | Silent (SNP) | VAF 19/363 reads (5%) | called by muse, mutect2
- ESPN | c.768C>T p.L256= | Silent (SNP) | VAF 58/551 reads (11%) | called by muse, mutect2, varscan2
- FREM3 | c.2874C>T p.D958= | Silent (SNP) | VAF 133/216 reads (62%) | catalogued as rs900565176; called by muse, mutect2, varscan2
- GABRD | c.717G>T p.L239= | Silent (SNP) | VAF 78/321 reads (24%) | called by muse, mutect2, varscan2
- HDGFL1 | c.396G>A p.P132= | Silent (SNP) | VAF 162/600 reads (27%) | catalogued as rs745407874, COSV100014763; called by muse, mutect2, varscan2
- KCNA1 | c.279C>T p.L93= | Silent (SNP) | VAF 40/273 reads (15%) | called by muse, mutect2, varscan2
- KRT72 | c.237C>T p.F79= | Silent (SNP) | VAF 56/680 reads (8%) | catalogued as COSV53376064; called by muse, mutect2
- MTX3 | c.744C>T p.I248= (on ENST00000512528 / NM_001363818.2; = p.I187= on NM_001167741.2) | Silent (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- NLRP2 | c.933G>A p.K311= | Silent (SNP) | VAF 62/1440 reads (4%) | catalogued as rs766281794; called by muse, mutect2
- NLRP4 | c.2967C>T p.I989= | Silent (SNP) | VAF 143/673 reads (21%) | called by muse, mutect2, varscan2
- PI4KB | c.1167C>T p.L389= (on ENST00000368873 / NM_001369623.1; = p.L401= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/357 reads (6%) | called by muse, mutect2
- TRIM75P | c.921G>C p.L307= | Silent (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- TRPC5 | c.1620C>T p.F540= | Silent (SNP) | VAF 34/507 reads (7%) | catalogued as COSV53293807; called by muse, mutect2
- USP16 | c.1641G>A p.E547= | Silent (SNP) | VAF 31/413 reads (8%) | catalogued as rs749872857; called by muse, mutect2
- VNN1 | c.165G>A p.R55= | Silent (SNP) | VAF 12/308 reads (4%) | catalogued as COSV100907799; called by muse, mutect2
- ATP13A4 | c.1674+25C>G | Intron (SNP) | VAF 40/396 reads (10%) | called by muse, mutect2, varscan2
- SYNE2 | c.18038+814G>A | Intron (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2, varscan2
